Somatic mutation profile of tumor specimen 0DR9C3 from CCDI case PBCFPX, project CCDI-MCI: Molecular Characterization Initiative (MCI). Sex at birth: male; Primary diagnosis: Synovial sarcoma, NOS; Tissue or organ of origin: Connective, subcutaneous and other soft tissues of lower limb and hip; Age at diagnosis: 13.8 years (5,040 days).
Specimen 0DR9C3: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) ea38a884-aead-4b07-a0ab-bb51538f4c11.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen 0DR9CQ (Peripheral Whole Blood; tissue type Normal); read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/b896e3f3-c0f9-4614-97ea-a1e90e7e2c7f

The open-access MAF lists 11 somatic variants for this specimen: 5 protein-altering or splice-affecting, 1 silent, 5 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 5, RNA 2, Intron 2, Silent 1, 5'UTR 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- DEPDC4 | c.593A>G p.E198G | Missense Mutation (SNP) | VAF 265/747 reads (35%) | SIFT tolerated (0.21); PolyPhen benign (0); catalogued as rs1287725384; called by muse, varscan2
- REPIN1 | c.1037C>T p.A346V | Missense Mutation (SNP) | VAF 232/596 reads (39%) | SIFT tolerated (0.25); PolyPhen benign (0); catalogued as COSV101262561; called by muse, mutect2, varscan2
- C17orf80 | c.843C>G p.S281R | Missense Mutation (SNP) | VAF 58/2045 reads (3%) | SIFT deleterious (0.05); PolyPhen benign (0.003); called by muse, mutect2
- TLR7 | c.1180C>T p.H394Y | Missense Mutation (SNP) | VAF 816/932 reads (88%) | SIFT tolerated (1); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- ZFHX4 | c.2923G>T p.A975S | Missense Mutation (SNP) | VAF 744/1888 reads (39%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.515); called by muse, mutect2, varscan2
- ARL14EPL | c.15A>C p.S5= | Silent (SNP) | VAF 434/1057 reads (41%) | called by muse, mutect2, varscan2
- AP3M2 | c.804-32G>A | Intron (SNP) | VAF 238/544 reads (44%) | catalogued as rs746885812; called by muse, mutect2, varscan2
- DNAH17 | c.5082+24C>T | Intron (SNP) | VAF 130/355 reads (37%) | catalogued as rs762194373; called by muse, mutect2, varscan2
- LINC01446 | n.1672T>G | RNA (SNP) | VAF 153/336 reads (46%) | called by muse, mutect2, varscan2
- LINC02694 | n.551T>C | RNA (SNP) | VAF 24/586 reads (4%) | called by muse, mutect2
- TARS3 | c.-33C>T | 5'UTR (SNP) | VAF 96/190 reads (51%) | called by muse, mutect2, varscan2
